Gene-level copy-number profile of tumor specimen TCGA-QK-AA3K-01A from TCGA case TCGA-QK-AA3K, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.5 years (22,093 days).
Specimen TCGA-QK-AA3K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c547f4be-fcaf-41a7-a920-067b5b261082.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-AA3K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e168acf5-72c7-4b9b-ac74-a541ccf924d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 6,473; copy number 2: 38,101; copy number 3: 11,565; copy number 4: 646; copy number 5: 2,245; copy number 8: 350; copy number 9: 360; copy number 14: 10; copy number 19: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-AA3K-01A-11D-A390-01): tumor purity 0.46, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,231,423–142,131,016, 1 gene (within-gene range 0–2): LRP1B.
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr4:119,212,587–119,295,517, 1 gene (within-gene range 0–3): USP53.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,019 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:147,844,123–174,378,005, 408 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 8–9 (broad region; genes not listed).
- chr7:6,952,625–47,948,466, 682 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr9:32,783,540–43,045,120, 363 genes, copy number 5 (broad region; genes not listed).
- chr9:103,689,473–138,203,325, 792 genes, copy number 5 (broad region; genes not listed).
- chr11:68,683,779–71,252,577, 64 genes, copy number 14–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,052. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
